Surgical pathology report (de-identified scan), TCGA case TCGA-XT-AASU, project TCGA-MESO (Mesothelioma), tissue source site Johns Hopkins, specimen TCGA-XT-AASU-01A (Primary Tumor).

[page 1 of 8]
SURGICAL
PATHOLOGY

* AMENDED *

=====

INTERPRETATION AND DIAGNOSIS:

- 1) SKIN "RIGHT PORT SITE" (EXCISION): SKIN WITH CHRONIC INFLAMMATION
NEGATIVE FOR TUMOR.
- 2) 6TH RIB (RESECTION: RIB (GROSS DIAGNOSIS).
- 3) R4 LYMPH NODE (LYMPHADENECTOMY): ONE (1) LYMPH NODE AND
ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.
- 4) R8 LYMPH NODE (LYMPHADENECTOMY): TWO (2) LYMPH NODES AND
ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.
- 5) STATION 7 LYMPH NODE (LYMPHADENECTOMY): ONE (1) LYMPH NODE AND
ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.
- 6) RIGHT LUNG AND PLEURA (PNEUMONECTOMY):
MIXED SARCOMATOID AND EPITHELIOID MALIGNANT MESOTHELIOMA. THE TUMOR
INVOLVES BOTH THE VISCERAL AND PARIETAL PLEURA, CHEST WALL, DIAPHRAGM
AND THE PERICARDIUM. THE TUMOR INVOLVES THE LUNG PARENCHYMA. THE
TUMOR EXTENDS CLOSE TO THE MARGIN OF RESECTION AT THE APEX, LATERAL AND
POSTERIOR MARGIN AND IS IN THE SOFT TISSUE OF THE BRONCHIAL MARGIN.
FIVE (5) HILAR LYMPH NODES ARE NEGATIVE FOR TUMOR. ONE LYMPH NODE
CONTAINS AN ASBESTOS BODY. THE NON-TUMOR LUNG SHOWS ESSENTIALLY NO
INTERSTITIAL FIBROSIS OR BRONCHIOLAR LUMINAL FIBROSIS. AT LEAST ONE
CHARACTERISTIC ASBESTOSIS BODY IS SEEN ON IRON STAINS IN EACH OF TWO
SLIDES (6C, 6H). A SINGLE "MINUTE" MENINGOTHELIAL NODULE IS PRESENT
(6C).
- 7) POSTERIOR DIAPHRAGMATIC SULCUS (RESECTION): MALIGNANT
MESOTHELIOMA INVADING INTO, BUT NOT THROUGH, THE DIAPHRAGM.
- 8) A3 LYMPH NODE (LYMPHADENECTOMY): FIVE (5) LYMPH NODES AND
ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

NOTE ADDED Immunostain for EGFR is strongly positive in the
epithelioid parts of the tumor, and only focally and weakly positive
in the spindle component.

ICD-O-3

(Continued on next page.)

Mesothelioma, lymphatic, malignant 905313
Site (Pleura) NOS C38.4

JLW 3/10/14

[page 2 of 8]
SURGICAL
PATHOLOGY

=====

Amended to add immunostain results, the diagnosis is not changed.

*Electronic signature

=====

Clinical History:
MESOTHELIOMA

GROSS DESCRIPTION

PART #1: RIGHT PORT SITE
Resident Pathologist:

Dictated by Dr.

The specimen is received fresh labeled [REDACTED] and designate "Right port site." The specimen consists of a strip of lightly pigmented skin with soft tissue underlying it. It measures 3.8 cm in length, has a maximum width of 0.4 cm and maximum thickness of 0.6 cm. The deep and lateral surface is inked black and the entire specimen is submitted in one cassette.

SUMMARY OF SECTIONS

1 - A - 1
1 - TOTAL - 1

PART #2: 6TH RIB
Resident Pathologist:

Dictated by

The specimen is received fresh labeled [REDACTED] and designated "6th rib-gross only." The specimen consists of two fragments of bone grossly consistent with rib. The larger bone measures 16.5 cm in length and has an average cross sectional area of 1.6 x 1.2 cm. The shorter fragment of bone measures 8 cm in length and has an average cross sectional area of 1.5 x 0.7 cm. There is only a very scant amount of soft tissue adhered to the bone. This is for gross diagnosis

(Continued on next page.)

[page 3 of 8]
SURGICAL
PATHOLOGY

=====

only. There will be no histologic sections generated.

PART #3: R-4 LYMPH NODE
Resident Pathologist:

Dictated by

The specimen is received fresh [REDACTED] and designated "R4 lymph node." The specimen consists of a portion of red-brown-black soft tissue that measures 1 x 0.7 x 0.5 cm. This tissue is placed in cassette and submitted in its entirety.

SUMMARY OF SECTIONS

1 - A - 1
1 - TOTAL - 1

PART #4: R-8 LYMPH NODE
Resident Pathologist:

Dictated by

The specimen is received fresh labeled [REDACTED] and designated "R8 lymph node." The specimen consists of a portion of yellow and dark red fatty tissue that measures 1.5 x 0.6 x 0.6 cm. The specimen is bisected and both bisected halves are entirely submitted in one cassette.

SUMMARY OF SECTIONS

1 - A - 2
1 - TOTAL - 2

(Continued on next page.)

[page 4 of 8]
[REDACTED]
[REDACTED]
SURGICAL
PATHOLOGY

Page 4

=====
PART #5: STATION 7
Resident Pathologist:

Dictated by

The specimen is received fresh labeled [REDACTED] and designated "Station 7." The specimen consists of a portion of red-brown soft tissue that measures 4.5 x 2.5 x 1 cm. It appears to be one very large lymph node. This presumed large lymph node is sectioned multiple times and the other pieces are submitted in their entirety.

SUMMARY OF SECTIONS

1 - A - 4
1 - B - 3
1 - C - 2
3 - TOTAL - 9

(Continued on next page.)

[page 5 of 8]
SURGICAL
PATHOLOGY

PART #6: RIGHT LUNG AND PLEURA
Resident Pathologist: ,

Dictated by

The specimen is received fresh labeled [REDACTED] and designated right lung and pleura. It consists of a right lung with associated pleura, diaphragm, and portion of what appears to be pericardial tissue. Overall, the specimen measures 26 x 19.5 x 18 cm. This includes a 18 x 16 x 6 cm lung and pleura and an 11.5 x 15.5 x 2 cm segment of attached diaphragm. The entire specimen weighs 1185 gms. A 7.5 x 3 x 0.2 cm portion of pericardial tissue is noted on the mediastinal surface of the lung. The lung appears to be completely encased by a nodular membrane. The nodular membrane varies in color from tan-pink to brown, and is continuous from the surface of the lung onto the surface of the attached diaphragm. The nodules vary in size from approximately 0.4 cm in greatest dimension to as large as 2 cm in greatest dimension. The abdominal surface of the diaphragm consists primarily of skeletal muscle; however, underlying nodularity is evident.

Examination of cut sections, reveals a thick core of firm white tissue entirely encasing the lung. This core of white tissue varies in thickness from 0.4 cm to 1 cm. This firm white mass extends into the interlobar fissures. The thick firm white tissue also extends into the posterior sulcus. The mass appears to invade deeply into the diaphragm, and grossly appears to extend to the abdominal surface of the diaphragm diffusely. Examination of cut sections, in the area of the presumed adhered pericardium, reveals the firm nodular mass appears to extend nearly to the surface of the pericardial membrane. Examination of the lung parenchyma reveals tan red soft parenchyma without any discrete masses or lesions. The lung does not appear to be particularly fibrotic nor cystic, but does appear to be somewhat compressed. Tissue is harvested for future possible studies.

SUMMARY OF SECTIONS:

1	- A	- M	(VASCULAR MARGIN)
1	- B	- 1	(BRONCHIAL MARGIN)
1	= C	- 1	(REP. SECTIONS OF UPPER LOBE LUNG PARENCHYMA PERIPHERAL)
1	--D	- 1	(REP. SECTIONS OF UPPER LOBE LUNG PARENCHYMA CENTRAL)

(Continued on next page.)

[page 6 of 8]
SURGICAL
PATHOLOGY

```
=====
1      = E      = 1  (REP. SECTIONS OF MIDDLE LOBE LUNG PARENCHYMA)
1      = F      - 1  (MIDDLE LOBE LUNG PARENCHYMA CENTRAL)
1      = G      - 1  (LOWER LOBE LUNG PARENCHYMA PERIPHERAL)
1      = H      - 1  (LOWER LOBE LUNG PARENCHYMA CENTRAL)
1      - I      - 1  (LUNG APEX MARGIN)
1      - J      - 1  (LATERAL MID MARGIN)
1      = K      - 1  ( LATERAL INFERIOR MARGIN)
1      = L      - 1  (POSTERIOR MARGIN)
1      - M      - 1  (ANTERIOR MARGIN)
1      -N      -1   (MEDIAL MARGIN)
1      -O      - 2  (PERICARDIUM)
1      -P      - 1  (DIAPHRAGM AND POSTERIOR SULCUS)
1      -Q      - 1  (LUNG AND DIAPHRAGM)
1      = R      - 1  (FISSURE BETWEEN UPPER AND LOWER LOBE)
1      = S      - 1  (NODULARITY IN THE LUNG IMMEDIATELY BENEATH THE
PERICARDIUM)
1      =T-U     = 1  EA. (HILAR AND LYMPH NODE STRUCTURES)
21     -TOTAL   - M
```

(Continued on next page.)

[page 7 of 8]
[REDACTED]

[REDACTED]

Page 7

SURGICAL
PATHOLOGY

=====

PART #7: POSTERIOR SULCUS TUMOR
Resident Pathologist:

Dictated by

The specimen is received fresh labeled [REDACTED] and designated "Posterior sulcus tumor." The specimen consists of a portion of diaphragm with what appears to be a small portion of the periesophageal ligament. It measures 21 x 12 cm and is approximately 2.5 cm at its thickness. The pleural surface appears to be completely covered with a firm white mass. Examination of the abdominal surface reveals only skeletal muscle and the aforementioned periesophageal ligament. Examination of cut section reveals the white mass to infiltrate into the diaphragmatic muscle, but in no where does it grossly appear to perforate to the other side into the abdominal surface. Several full thickness sections are taken to sample the lesion. Beginning at the end opposite the periesophageal ligament (block "A"). With the final section being through the periesophageal ligament (block "B").

SUMMARY OF SECTIONS

1 - A - 1 (OPPOSITE PERIESOPHAGEAL LIGAMENT)
3 - B-D - 1 EACH
1 - E - 1 (PERIESOPHAGEAL LIGAMENT)
5 - TOTAL - 5

(Continued on next page.)

[page 8 of 8]
SURGICAL
PATHOLOGY

PART #8: A-3 LYMPH NODE
Resident Pathologist:

Dictated by

The specimen is received fresh labeled [REDACTED] and designated "A3 lymph node." The specimen consists of a 4.5 x 1.5 x 0.6 cm fragment of black-yellow-red fibrofatty tissue. Five possible lymph nodes are grossly identified. The largest of these measures 3 x 1.5 x 0.5 cm. This large lymph node is bisected and submitted. All the other lymph nodes are submitted in full.

SUMMARY OF SECTIONS

- 1 - A - 2 (LARGEST POSSIBLE LYMPH NODE BISECTED)
- 1 - B - 4 (FOUR POSSIBLE LYMPH NODES)
- 1 - C - M (FATTY TISSUE)
- 3 - TOTAL - M

Other Surgical Pathology Specimens known to the computer: [REDACTED]

(End of Report)

printed

Source: NCI Genomic Data Commons file 4af65ae5-2806-43d1-abd0-ac31d34e42c8 (TCGA-XT-AASU.C8BD557C-7182-404C-A6BB-066CD61D2654.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).